Surgical pathology report (de-identified scan), TCGA case TCGA-B5-A0K7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Duke, specimen TCGA-B5-A0K7-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Adenocarcinoma, endometrioid, Nos 8380/3

Site: Endometrium C54.1 w/ 2/25/11

Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri.

GROSS EXAMINATION:

A. "Peritoneal biopsy (AF1)", unfixed for frozen section and placed in formalin at 12 pm on is a 8 x 8 x 8 mm fragment of tissue, entirely submitted in A1.

B. "Uterus and bilateral adnexa (BF1)", unfixed for frozen section placed in formalin at 12 pm on is a 135 gm, 11.1 x 7 x 4.2 cm hysterectomy specimen.

There is 6 x 3.5 x 0.4 cm exophytic mass that involves the uterine isthmus, the lower uterine segment and the superior part of the cervix. The mass involves both the interior and posterior surfaces. It did not appear to penetrate the 1.5 cm thick myometrium. In addition, there is a 9.6 x 6.7 x 1.8 cm aggregate of tumor and blood clot that came out of the endometrial cavity when it was opened. Otherwise, the serosal surface and myometrium are unremarkable. Right and left ovaries and fallopian tubes are unremarkable.

BLOCK SUMMARY:

B1 AF1 remnant (representative mass from posterior wall)
B2-3 mass on anterior wall
B4-5 mass on posterior wall
B6 mass in anterior lower uterine segment
B7 mass in posterior lower uterine segment
B8-B9 cervix
B10-B11 mass from endometrial cavity
B12-B13 representative myometrium
B14-B15 bilateral tubes & ovaries

C. "Left pelvic nodes", unfixed, transferred to formalin at 1 pm on is a 5 x 2 x 1.5 cm aggregate of adipose tissue, in which five lymph nodes up to 3.5 cm are found.

C1-C2 multiple lymph nodes
C3 intact lymph node

D. "Right pelvic lymph nodes", unfixed, transferred to formalin at 1 pm on is a 3 x 1.5 x 0.6 cm aggregate of fibroadipose tissue, in which one 1 x 0.8 x 0.3 cm lymph node is identified. This is sectioned and submitted in D1. The remainder of the tissue is submitted in D2.

REPORT REVISED ON Dr. /Dr.
AT

INTRA OPERATIVE CONSULTATION:

A. "Peritoneal biopsy" (AF1, in toto): favor reactive (Dr.

B. "Uterus, cervix, bilateral tubes & ovaries" (BF1, 1.5 cm thick myometrium): endometrioid adenocarcinoma, minimally invasive at most, FIGO grade 1 in this representative section

REPORT REVISED ON

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

Dual/Synchronous Primary	Noted	

[page 2 of 2]
PATHOLOGIC STAGE:
pT1aN0

DIAGNOSIS:

A. "PERITONEAL" (BIOPSY):

NEGATIVE FOR MALIGNANCY.

B. "UTERUS (135 G) AND BILATERAL ADNEXA" (HYSTERECTOMY):

ENDOMETRIUM:

Histologic type:

FIGO Grade:

Size:

Vascular invasion:

ENDOMETRIOID ADENOCARCINOMA ✓

1
6.0 x 3.5 x 04 CM ✓

NOT IDENTIFIED

MYOMETRIUM:

Depth of invasion:

NEGATIVE FOR MYOMETRIAL INVASION

CERVIX:

Tumor extension:

SURFACE EXTENSION ONLY;
NEGATIVE FOR STROMAL INVASION

PARAMETRIUM/SEROSA:

Tumor extension:

NEGATIVE

BILATERAL OVARIES & FALLOPIAN TUBES, NEGATIVE FOR MALIGNANCY

C. "LEFT PELVIC NODES" (BIOPSY):

FIVE LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/5).

D. "RIGHT PELVIC LYMPH NODES" (BIOPSY):

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5d87e6be-b57a-4510-8eb2-95fa5bf918e7 (TCGA-B5-A0K7.5C3818CE-5DA9-403E-B895-61DEA4BBFA57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).